Somatic mutation profile of tumor specimen TCGA-FG-5964-01A (aliquot TCGA-FG-5964-01A-11D-1705-08) from TCGA case TCGA-FG-5964, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 62.2 years (22,735 days).
Specimen TCGA-FG-5964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dda0b107-e5b5-45d8-83ee-e5a1be340517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5964-10A (Blood Derived Normal), aliquot TCGA-FG-5964-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45c3b230-13b2-472b-acfe-3c41796df4cd

The open-access MAF lists 37 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Frame Shift Del 6, In Frame Del 6, Silent 4, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.17_18del p.K6Rfs*4 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | catalogued as rs121913290; ClinVar: pathogenic; called by mutect2, varscan2
- AKR1C3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs782183912, COSV65911080; called by muse, mutect2, varscan2
- ALMS1 | c.12490A>G p.K4164E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52520513; called by muse, mutect2, varscan2
- BBS7 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs751170388, COSV52659184; called by muse, mutect2, varscan2
- BRINP2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64177024; called by muse, mutect2, varscan2
- C12orf65 | c.139_141del p.K47del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs767823614; called by pindel, varscan2
- CAST | c.700G>A p.A234T (on ENST00000341926; = p.A317T on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368744741, COSV57789030; called by muse, mutect2, varscan2
- CCR10 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV52853969; called by muse, mutect2, varscan2
- CLCN7 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs200960952; called by muse, mutect2, varscan2
- EVX1 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56085956; called by muse, mutect2
- H3C3 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV63551485; called by muse, mutect2, varscan2
- HCLS1 | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57527107; called by muse, mutect2, varscan2
- KIAA1217 | c.3524A>T p.K1175M | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56822574; called by muse, mutect2
- KLC1 | c.1471A>G p.M491V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs568689263, COSV55811083; called by muse, mutect2, varscan2
- LRP1 | c.8173G>A p.E2725K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.27); catalogued as rs987146512, COSV54506487; called by muse, mutect2, varscan2
- MARCO | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs369805550; called by muse, mutect2, varscan2
- MRPS18B | c.96_97del p.C33Hfs*6 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as rs749369142; called by mutect2, pindel, varscan2
- MYO5A | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.166); catalogued as COSV62564079; called by muse, mutect2, varscan2
- NCAPH2 | c.267-1G>A p.X89_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as COSV55370729; called by muse, mutect2, varscan2
- NRCAM | c.3205A>G p.R1069G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as rs1233083176, COSV61047588; called by muse, mutect2, varscan2
- OBSCN | c.18033G>A p.W6011* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV52781790; called by muse, mutect2, varscan2
- OR1A1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772402283, COSV58403180; called by muse, mutect2, varscan2
- SPANXD | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 75/124 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV65152505; called by muse, mutect2, varscan2
- CIC | c.4034_4035del p.V1345Gfs*16 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- CLK1 | c.93_96del p.K32Dfs*30 | Frame Shift Del (DEL) | VAF 37/184 reads (20%) | called by pindel, varscan2
- NOP56 | c.267_269del p.K90del | In Frame Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- PAF1 | c.542_544del p.K181del | In Frame Del (DEL) | VAF 28/120 reads (23%) | called by pindel, varscan2
- PAN2 | c.617del p.N206Ifs*15 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- RBPJ | c.661_663del p.F221del | In Frame Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- TINF2 | c.1105_1107del p.L369del | In Frame Del (DEL) | VAF 15/88 reads (17%) | called by pindel, varscan2
- UBL3 | c.340_342del p.C114del | In Frame Del (DEL) | VAF 10/44 reads (23%) | called by pindel, varscan2
- ZFHX4 | c.10427_10430del p.I3476Nfs*4 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- CCZ1B | c.609T>C p.Y203= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs1477450975; called by muse, mutect2, varscan2
- CDH15 | c.2238G>A p.A746= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs748042060, COSV57027003; called by muse, mutect2, varscan2
- FUCA2 | c.1041A>G p.V347= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV50020930; called by muse, mutect2, varscan2
- SIPA1L2 | c.2100G>A p.R700= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV53398587; called by muse, mutect2, varscan2
